Somatic mutation profile of tumor specimen TCGA-14-3477-01A (aliquot TCGA-14-3477-01A-01W-0922-08) from TCGA case TCGA-14-3477, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.6 years (14,082 days).
Specimen TCGA-14-3477-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 478a8608-334e-4d9d-a3c3-fb138214fdbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-3477-10A (Blood Derived Normal), aliquot TCGA-14-3477-10A-01W-0922-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/548fcdcc-9713-4fc5-b91c-19971426cb12

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 246/254 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCG4 | c.921C>G p.D307E | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100266602; called by muse, mutect2
- BAZ2B | c.5123A>G p.K1708R | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV58601215; called by muse, mutect2, varscan2
- CAND2 | c.2293G>T p.V765L (on ENST00000456430 / NM_001162499.2; = p.V672L on NM_012298.3) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV99928778; called by muse, mutect2, varscan2
- CASD1 | c.1517T>C p.I506T | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1407024435, COSV51972602; called by muse, varscan2
- CHAT | c.1441dup p.R481Pfs*30 | Frame Shift Ins (INS) | VAF 10/96 reads (10%) | catalogued as rs773268576; called by mutect2, pindel
- DOCK5 | c.3541C>T p.R1181W | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs780213767, COSV52416302; called by muse, mutect2, varscan2
- ECEL1 | c.2288A>G p.D763G | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58812395; called by muse, mutect2, varscan2
- ERN1 | c.2476G>A p.V826M | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs758266847, COSV101458403; called by muse, mutect2, varscan2
- FIBCD1 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs1019642247, COSV53394663; called by muse, mutect2, varscan2
- FLG | c.5907C>A p.H1969Q | Missense Mutation (SNP) | VAF 238/778 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV64242120; called by muse, mutect2
- GAB2 | c.1561C>T p.R521W (on ENST00000361507 / NM_080491.3; = p.R483W on NM_012296.3) | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs763198440, COSV60868031; called by muse, mutect2, varscan2
- KCNC4 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs763803707, COSV100873586; called by mutect2, varscan2
- MTMR8 | c.2077G>A p.A693T | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV66394771; called by muse, mutect2, varscan2
- PAQR7 | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs143783991; called by muse, mutect2, varscan2
- PDCD2 | c.969C>A p.S323R | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51341166; called by muse, mutect2, varscan2
- PDCD2 | c.874C>G p.Q292E | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51341168; called by muse, mutect2, varscan2
- PDSS1 | c.1215G>C p.Q405H | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs574624767, COSV100697786; called by muse, mutect2, varscan2
- POLM | c.290dup p.A98Sfs*73 | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | catalogued as rs745933237; called by mutect2, varscan2
- RBM15B | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as COSV100081969; called by muse, mutect2
- RECQL | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.119); catalogued as COSV100131216, COSV59085294; called by muse, mutect2, varscan2
- RNASEH1 | c.510-2A>T p.X170_splice | Splice Site (SNP) | VAF 61/189 reads (32%) | catalogued as COSV59438696; called by muse, mutect2, varscan2
- SGK1 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV52808699; called by muse, mutect2, varscan2
- SLC28A2 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs767326360, COSV61664116; called by muse, varscan2
- SPATA16 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1190807037, COSV63529447; called by muse, mutect2, varscan2
- SYNE1 | c.22799C>G p.A7600G (on ENST00000367255 / NM_182961.4; = p.A7529G on NM_033071.3) | Missense Mutation (SNP) | VAF 130/391 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV54986963; called by muse, varscan2
- TBL1XR1 | c.139G>C p.A47P | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100763546; called by muse, mutect2, varscan2
- TLR7 | c.2539A>G p.I847V | Missense Mutation (SNP) | VAF 127/595 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66124348; called by muse, mutect2, varscan2
- UCHL1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV99449007; called by muse, mutect2, varscan2
- ZC3H12B | c.146T>A p.I49K | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as COSV100161578; called by muse, mutect2, varscan2
- ZNF18 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV59551359; called by muse, mutect2, varscan2
- DNHD1 | c.11241_11242del p.L3748Gfs*16 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by pindel, varscan2
- GRAP | c.316_328del p.Q106Cfs*153 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- PEX1 | c.3448_3463del p.C1150Afs*3 | Frame Shift Del (DEL) | VAF 19/141 reads (13%) | called by mutect2, pindel, varscan2
- PUM3 | c.1050_1061del p.I351_A354del | In Frame Del (DEL) | VAF 6/74 reads (8%) | called by mutect2, pindel
- ABCB11 | c.2760G>A p.R920= | Silent (SNP) | VAF 38/290 reads (13%) | catalogued as rs774052013, COSV55587167; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM83B | c.1746C>T p.D582= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs769176959, COSV100174194; called by muse, mutect2
- ITGA4 | c.2595G>A p.Q865= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as COSV101223187; called by muse, mutect2, varscan2
- KAT6A | c.5922G>A p.G1974= | Silent (SNP) | VAF 74/558 reads (13%) | catalogued as COSV99704633; called by muse, mutect2, varscan2
- LRRC8B | c.1938T>G p.A646= | Silent (SNP) | VAF 95/191 reads (50%) | catalogued as COSV58374885; called by muse, mutect2, varscan2
- MED14 | c.2943C>T p.D981= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs999946636, COSV61356918; called by muse, mutect2, varscan2
- SGK1 | c.978C>T p.H326= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs376904641; called by muse, mutect2, varscan2
- SH3KBP1 | c.621C>A p.P207= | Silent (SNP) | VAF 76/381 reads (20%) | catalogued as COSV65641444; called by muse, mutect2, varscan2
- TNFRSF8 | c.693G>A p.Q231= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV55796651; called by muse, mutect2, varscan2
- ZNF800 | c.1137A>G p.Q379= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as COSV56175881; called by muse, mutect2, varscan2
